Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8346, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8346-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

■ year old male with kidney mass, (right).

Specimens Submitted:

1: SP: Kidney, right, nephrectomy

2: SP: Lymph nodes, right precaval and paracaval, excision

DIAGNOSIS:

1. SP: Kidney, right, nephrectomy:

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 11 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Exhibits patchy chronic interstitial inflammation and fibrosis, and glomerular sclerosis.

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

Comment: Prominent nuclear atypia is present.

2. SP: Lymph nodes, right precaval and paracaval, excision:

Lymph Nodes:

Not involved

Number of nodes examined:1

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh, labeled "right radical nephrectomy" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 771 g in total. The kidney measures 12 x 7 x 6 cm. The attached ureter measures 8.5 cm in length and 0.2 cm in diameter. The attached renal vein measures 0.2 cm in length and 0.5 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a 11 x 9 x 7 cm necrotic, lobulated yellow and hemorrhagic mass in the lower pole extending to the mid kidney and renal pelvis. The mass entirely replaces the lower portion of the kidney. The mass grossly extends to the renal capsule but does not penetrate through it. The mass appears to extend into the perihilar fat. Sections through the remainder of the kidney reveal a pink-brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.2 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

TC -- tumor with capsule

2). The specimen is received in formalin, labeled "Right precaval and paracaval lymph nodes" and consists of a single brown-tan fleshy lymph node measuring 7 x 1 x 0.6 cm. The lymph node is trisected and entirely submitted.

Summary of sections:

T- trisected lymph node

Summary of Sections:

Part 1: SP: Kidney, right, nephrectomy

Block	Sect. Site	PCs
1	k	1
1	rp	1
9	t	9
2	tc	2
3	thf	3
1	tk	1
1	uvm	1

Part 2: SP: Lymph nodes, right precaval and paracaval, excision

Block	Sect. Site	PCs
3	T	3

Source: NCI Genomic Data Commons file 19f6f9f1-e91e-4745-af4d-391c75f75715 (TCGA-KL-8346.36D69D54-A29D-43EF-AB2F-4D24F62A9E2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).